Somatic mutation profile of tumor specimen TARGET-10-PAPSPN-04A (aliquot TARGET-10-PAPSPN-04A-01D) from TARGET case TARGET-10-PAPSPN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.4 years (4,173 days).
Specimen TARGET-10-PAPSPN-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f266ba2-e8dd-4f45-93ca-701d9fa3528d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPSPN-10A (Blood Derived Normal), aliquot TARGET-10-PAPSPN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52e2dc20-7873-4be0-8efc-ebb50d732e08

The open-access MAF lists 54 somatic variants for this specimen: 45 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 7, Nonsense Mutation 3, Intron 1, Frame Shift Ins 1, In Frame Ins 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7A | c.2383C>T p.R795* | Nonsense Mutation (SNP) | VAF 326/354 reads (92%) | catalogued as rs72554645, CM970130, COSV58447199; ClinVar: pathogenic; called by muse, mutect2, varscan2
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 171/388 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 481/1127 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ADAM22 | c.1235A>C p.K412T | Missense Mutation (SNP) | VAF 249/785 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV55986724; called by muse, mutect2, varscan2
- ASPH | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 241/554 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs149440176; called by muse, mutect2, varscan2
- ATF1 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 208/458 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs146613889, COSV50395563; called by muse, mutect2, varscan2
- ATP11A | c.1079T>C p.I360T | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52119601; called by muse, mutect2, varscan2
- BRWD3 | c.3719G>C p.R1240P | Missense Mutation (SNP) | VAF 275/293 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV64752276, COSV64753268; called by muse, mutect2, varscan2
- CENPE | c.2947C>A p.L983I | Missense Mutation (SNP) | VAF 288/673 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV54387629; called by muse, varscan2
- CPEB2 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 272/592 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs747053768, COSV52589355, COSV52594540; called by muse, mutect2, varscan2
- CYP3A7 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 102/227 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as rs760875340, COSV60480907; called by muse, mutect2, varscan2
- DHX34 | c.3373G>T p.G1125W | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV60897497; called by muse, mutect2, varscan2
- DTX2 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs775816588, COSV56864204; called by muse, mutect2, varscan2
- ELAVL2 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 275/593 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.045); catalogued as COSV56368591; called by muse, mutect2, varscan2
- FBL | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1414848625, COSV55681944; called by muse, mutect2, varscan2
- GAL3ST1 | c.510C>G p.F170L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs769714165, COSV58891970, COSV58893380; called by muse, mutect2, varscan2
- GIGYF2 | c.2310_2311insGTTC p.R771Vfs*52 | Frame Shift Ins (INS) | VAF 74/193 reads (38%) | catalogued as COSV65248220; called by mutect2, pindel, varscan2
- HOOK1 | c.2065G>A p.G689S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1008809819, COSV64620423; called by muse, mutect2, varscan2
- IL1RAPL1 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 125/188 reads (66%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); catalogued as rs777978404, COSV56282731, COSV56285326; called by muse, mutect2, varscan2
- KIAA1109 | c.6836G>A p.R2279H | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763958504, COSV52687546; called by muse, mutect2, varscan2
- KIF13B | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 224/497 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.022); catalogued as rs780881097, COSV73054645; called by muse, mutect2, varscan2
- KMT2D | c.4472G>A p.W1491* | Nonsense Mutation (SNP) | VAF 50/172 reads (29%) | catalogued as COSV56474120; called by muse, mutect2, varscan2
- LCT | c.5174C>T p.T1725M | Missense Mutation (SNP) | VAF 111/227 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs1035870978, COSV51555505; called by muse, mutect2, varscan2
- LIFR | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 184/412 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.156); catalogued as rs1273235739, COSV54697471; called by muse, mutect2, varscan2
- MET | c.2378G>A p.R793H | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.944); catalogued as rs199643166; ClinVar: uncertain significance; called by muse, mutect2
- METTL4 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 173/416 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771372586, COSV60603959, COSV60604530; called by muse, mutect2, varscan2
- MYOCD | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 92/192 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs778429833, COSV58505020; called by muse, mutect2, varscan2
- NAA11 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 84/210 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs761201577, COSV54515009; called by muse, mutect2, varscan2
- NCOR2 | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62295879; called by muse, mutect2, varscan2
- NECTIN3 | c.1041A>T p.R347S | Missense Mutation (SNP) | VAF 254/523 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV60552940; called by muse, mutect2, varscan2
- NPEPPS | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 97/210 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs766039929, COSV59104656; called by muse, mutect2, varscan2
- NT5C2 | c.1224C>A p.S408R | Missense Mutation (SNP) | VAF 180/381 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.211); catalogued as COSV58418590; called by muse, mutect2, varscan2
- PRKACG | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV55255602; called by muse, mutect2, varscan2
- PRKN | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); catalogued as rs749768565, COSV100627580, COSV58224511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RICTOR | c.3420T>A p.D1140E | Missense Mutation (SNP) | VAF 235/530 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.199); catalogued as COSV57128334; called by muse, mutect2, varscan2
- SPON1 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375278612; called by muse, mutect2, varscan2
- SPTBN2 | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1340763076, COSV59451869; called by muse, mutect2, varscan2
- SRRT | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); catalogued as rs755711164, COSV53815232, COSV53818748; called by muse, mutect2, varscan2
- TMC7 | c.582C>G p.Y194* | Nonsense Mutation (SNP) | VAF 197/594 reads (33%) | catalogued as COSV58586808; called by muse, mutect2, varscan2
- TRIM29 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV59281788; called by muse, mutect2, varscan2
- USH2A | c.4646G>A p.R1549Q | Missense Mutation (SNP) | VAF 118/217 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as rs190170807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP26 | c.1461del p.F487Lfs*40 | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | catalogued as rs761320003; called by mutect2, varscan2
- XIRP2 | c.9422A>T p.N3141I (on ENST00000628543; = p.N3316I on NM_152381.6) | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV54725969, COSV99746523; called by muse, mutect2, varscan2
- ZNF519 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 339/729 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.027); catalogued as rs777481699; called by muse, mutect2, varscan2
- PAX5 | c.145_146insATGATCATCAAGGTGATG p.G48_V49insDDHQGD | In Frame Ins (INS) | VAF 31/86 reads (36%) | called by pindel, varscan2
- GPR156 | c.546G>A p.T182= | Silent (SNP) | VAF 59/131 reads (45%) | catalogued as rs750518057, COSV59939524; called by muse, mutect2, varscan2
- NOBOX | c.480G>A p.P160= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs368119264; called by muse, mutect2
- PEX14 | c.849C>T p.P283= | Silent (SNP) | VAF 86/189 reads (46%) | catalogued as rs752909373, COSV63062936; called by muse, mutect2, varscan2
- RFPL4B | c.348C>T p.S116= | Silent (SNP) | VAF 64/115 reads (56%) | catalogued as rs147620371, COSV71437811; called by muse, mutect2, varscan2
- SLC7A8 | c.1036C>A p.R346= | Silent (SNP) | VAF 73/144 reads (51%) | catalogued as COSV57553650, COSV57555479; called by muse, mutect2, varscan2
- SPEG | c.3495G>C p.S1165= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV100403065, COSV56666372; called by muse, mutect2, varscan2
- XPO6 | c.1104C>T p.I368= | Silent (SNP) | VAF 70/155 reads (45%) | catalogued as rs777809094, COSV58970012; called by muse, mutect2, varscan2
- IGLV5-45 | chr22:22376505 ins TC | 3'Flank (INS) | VAF 56/104 reads (54%) | called by mutect2, pindel, varscan2
- TTN | c.10360+2929G>A | Intron (SNP) | VAF 130/282 reads (46%) | catalogued as rs769428404, COSV59993112; called by muse, mutect2, varscan2
